Surgical pathology report (de-identified scan), TCGA case TCGA-KV-A6GD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Hartford, specimen TCGA-KV-A6GD-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

CC:

DIAGNOSIS

1. SOFT TISSUE, PERIRENAL FAT, EXCISION: FIBROADIPOSE TISSUE WITH FOCAL ACUTE INFLAMMATION; NEGATIVE FOR CARCINOMA.

2. RIGHT RENAL MASS, PARTIAL NEPHRECTOMY: PAPILLARY RENAL CELL CARCINOMA (SEE COMMENT).

Histologic type:
Sarcomatoid features:
Tumor Necrosis
Tumor size:
Fuhrman nuclear grade:
Tumor focality:
Macroscopic extent of tumor:
Microscopic extent of tumor:
Lymphatic/vascular invasion:
Margins:
Non-neoplastic kidney:

Adrenal gland:
Lymph nodes:
pTNM:
AJCC STAGE:

Papillary carcinoma, type 2 (chromophil cell)
Not identified
Present (~ 35%); see comment
6.5 cm
Grade 2, focal 3.
Unifocal
Confined to renal parenchyma.
Confined to renal parenchyma.
Absent.
Negative parenchymal resection and perinephric soft tissue margins.
Renal parenchyma with patchy chronic inflammation and blood vessels with mild peripheral vascular disease.
Not present.
No nodes submitted.
pT1b
Stage I

*CCF. ICD-O-3
Carcinoma, papillary
renal cell 8260/3
Path
Carcinoma, papillary NOS
8260/3
Site R Kidney NOS
C64.9
7/6/17/13*

Electronically Signed Out

COMMENT

The tumor necrosis could have occurred spontaneously however it is associated with the prior core biopsy site, so biopsy-induced necrosis is also possible. Prior studies on the core biopsy showed positive CK7 and positive AMACR consistent with papillary carcinoma.

#1 & #2: 88307, 88329

Clinical Diagnosis and History:

Right renal mass

Tissue(s) Submitted:

1: PERITONEAL FAT
2: RIGHT RENAL MASS

[page 2 of 2]
Surgical Pathology Report

Gross Description:

Specimen # 1 is received in formalin labeled perirenal fat and consist of a 8 x 8 x 1 cm fragment of adipose tissue partially surfaced by a glistening fascia. The specimen is serially sectioned to reveal no gross lesions. Representative sections are submitted in blocks 1A to 1B.

Specimen #2 labeled right renal mass is received fresh for intraoperative consultation and consists of 195 grams, 9.5 (L-M) x 7.0 (S-I) x 6 cm (A-P) partial nephrectomy specimen. The specimen is inked blue in the parenchymal margin and black on the perinephric adipose tissue and then serially sectioned to reveal a 6.5 x 6.5 x 3.5 cm tumor ant about 4 mm to the parenchymal margin and confined to the renal parenchyma. The tumor cut surface is variegated and necrotic (approximately 35% necrosis). A small amount of tumor is procured for . Representative sections are submitted as follows:

- 2A: Perirenal fat
- 2B-C: Tumor to parenchymal margin.
- 2D-E: Tumor to perinephritic fat.
- 2G-H: Tumor to adjacent kidney and representative tumor.

Intraoperative Consult Diagnosis

MASS MEASURES ~4MM FROM THE CLOSEST PARENCHYMAL MARGIN

HIS/AA Discrepancy		/
Reviewer Initials	BTB	Dr. C. Reviewed: 5/20/13

Source: NCI Genomic Data Commons file 92d0feec-85d5-4c7c-81c4-dbef35c7d026 (TCGA-KV-A6GD.516173EA-A413-434E-9F9A-0A1A107C5B3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).